Somatic mutation profile of tumor specimen TCGA-K1-A6RV-01A (aliquot TCGA-K1-A6RV-01A-11D-A32I-09) from TCGA case TCGA-K1-A6RV, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 67.6 years (24,701 days).
Specimen TCGA-K1-A6RV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc7fe0fc-65b6-4525-8bf0-40d1bcb44359.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-K1-A6RV-10A (Blood Derived Normal), aliquot TCGA-K1-A6RV-10A-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c396d658-d1b4-4215-ad85-d7352d61daac

The open-access MAF lists 73 somatic variants for this specimen: 57 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 51, Silent 16, Splice Site 3, Nonsense Mutation 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.645T>G p.S215R | Missense Mutation (SNP) | VAF 43/58 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057520001, CD941799, COSV52752255, COSV52783847, COSV52798196; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.7886G>A p.G2629E | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67997353; called by muse, mutect2, varscan2
- AGAP3 | c.128T>A p.V43E (on ENST00000622464; = p.V79E on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV99880308; called by muse, mutect2, varscan2
- AOC3 | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as rs779415396, COSV99520031; called by muse, mutect2, varscan2
- AP1M1 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.631); catalogued as rs999036825, COSV52226610; called by muse, mutect2, varscan2
- ARHGAP27 | c.1502G>T p.G501V (on ENST00000428638 / NM_001282290.1; = p.G160V on NM_199282.3) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100976535; called by muse, mutect2, varscan2
- BLNK | c.1306C>G p.L436V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56410464, COSV99813929; called by muse, mutect2
- BTN1A1 | c.623T>C p.I208T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as COSV99764404; called by muse, mutect2, varscan2
- C9orf43 | c.1232T>C p.V411A | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV99928373; called by muse, mutect2, varscan2
- CD84 | c.169A>G p.K57E | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs1557980231, COSV100246034; called by muse, mutect2, varscan2
- CHRNA4 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs78695425, COSV100937418; called by muse, mutect2, varscan2
- COL4A1 | c.3031G>T p.G1011* | Nonsense Mutation (SNP) | VAF 23/67 reads (34%) | catalogued as rs1566351231, COSV101011195, COSV101011605; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPS4 | c.913A>T p.I305F | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.166); catalogued as COSV100018560; called by muse, mutect2, varscan2
- CSPG4 | c.3570G>C p.Q1190H | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1476243532, COSV100413797; called by muse, mutect2, varscan2
- DAZL | c.359G>T p.C120F | Missense Mutation (SNP) | VAF 111/246 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.786); catalogued as rs773266331, COSV99167497; called by muse, mutect2, varscan2
- DDX60 | c.2210G>A p.R737Q | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs574811561, COSV67094944; called by muse, mutect2, varscan2
- DGKG | c.2339T>C p.F780S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV99403413; called by muse, mutect2, varscan2
- DOCK2 | c.3784G>A p.V1262I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV99912603; called by muse, mutect2, varscan2
- DSG2 | c.1606A>G p.K536E | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99853193; called by muse, mutect2, varscan2
- ERBIN | c.1947C>A p.H649Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.05); catalogued as COSV99396913; called by muse, mutect2
- FGG | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs141597421, COSV60196005; called by muse, mutect2, varscan2
- GPAA1 | c.1121A>G p.Y374C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100284077; called by muse, mutect2, varscan2
- GRM5 | c.1897T>G p.F633V | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100552130; called by muse, mutect2, varscan2
- GZF1 | c.141G>A p.M47I | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.48); PolyPhen benign (0.037); catalogued as COSV100582553; called by muse, mutect2, varscan2
- INTS5 | c.736G>T p.G246C | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100399639; called by muse, mutect2, varscan2
- JPH2 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 55/85 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65906320; called by muse, mutect2, varscan2
- KBTBD12 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as COSV100675438; called by muse, mutect2, varscan2
- KCNH7 | c.2114A>G p.Q705R | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV100036044; called by muse, mutect2, varscan2
- KIF1A | c.2220C>G p.S740R | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV100241079; called by muse, varscan2
- KLC3 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV101228898, COSV67271139; called by muse, mutect2, varscan2
- LRP5 | c.4090G>T p.G1364C | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99592046; called by muse, mutect2, varscan2
- MCF2L | c.1813C>T p.R605W (on ENST00000375608; = p.R573W on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs778131865, COSV100982593, COSV100982748; called by muse, mutect2, varscan2
- MIP | c.322A>T p.T108S | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.746); catalogued as COSV99234278; called by muse, mutect2, varscan2
- MYRIP | c.1520C>T p.T507I | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.825); catalogued as COSV100219265; called by muse, mutect2, varscan2
- NADK | c.1185-2A>T p.X395_splice | Splice Site (SNP) | VAF 56/71 reads (79%) | catalogued as COSV100410878; called by muse, mutect2, varscan2
- NOS2 | c.2749A>G p.T917A | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.111); catalogued as COSV58221419; called by muse, mutect2, varscan2
- OTUD4 | c.886C>G p.H296D (on ENST00000447906 / NM_001366057.1; = p.H231D on NM_001102653.1) | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as COSV101485990; called by muse, mutect2
- PKHD1L1 | c.10834A>C p.T3612P | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV101006173; called by muse, mutect2, varscan2
- PRDM16 | c.1571C>A p.P524H | Missense Mutation (SNP) | VAF 40/52 reads (77%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.888); catalogued as COSV99576795; called by muse, mutect2, varscan2
- PTCH1 | c.2703+1G>C p.X901_splice | Splice Site (SNP) | VAF 13/84 reads (15%) | catalogued as CS146517, COSV100108716; called by muse, mutect2, varscan2
- PZP | c.3107A>G p.E1036G | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.593); catalogued as COSV99737953; called by muse, mutect2, varscan2
- RASA1 | c.1105G>A p.G369S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99169845; called by muse, varscan2
- RASA1 | c.1230G>A p.M410I | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV99169847; called by muse, varscan2
- SHE | c.439C>A p.L147I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV100496046; called by muse, mutect2, varscan2
- SLC26A9 | c.1693A>C p.K565Q | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); catalogued as COSV100536401; called by muse, mutect2, varscan2
- SORBS1 | c.1790G>C p.R597T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as COSV53354569, COSV53359430; called by muse, mutect2, varscan2
- SPATA5 | c.1979C>T p.P660L | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99915524; called by muse, mutect2, varscan2
- SSH3 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs756680076, COSV57386296; called by muse, mutect2, varscan2
- TEKT2 | c.953T>A p.L318Q | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99255535; called by muse, mutect2, varscan2
- TH | c.557T>G p.V186G (on ENST00000381178 / NM_199292.3; = p.V155G on NM_000360.4) | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.889); catalogued as COSV100147100; called by muse, mutect2, varscan2
- UGT3A2 | c.902G>A p.G301D | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99236396; called by muse, mutect2, varscan2
- WDR36 | c.751A>G p.T251A | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV101540805; called by muse, mutect2, varscan2
- WDR70 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1171474342, COSV99458958; called by muse, mutect2, varscan2
- YME1L1 | c.2092-2A>G p.X698_splice (on ENST00000326799 / NM_139312.3; = p.X641_splice on NM_014263.4) | Splice Site (SNP) | VAF 6/41 reads (15%) | catalogued as COSV100463697; called by muse, mutect2, varscan2
- ZNF234 | c.1521_1522del p.K510Tfs*3 | Frame Shift Del (DEL) | VAF 37/125 reads (30%) | catalogued as rs768145235; called by mutect2, pindel, varscan2
- ZNF277 | c.61T>A p.C21S | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV100702436; called by muse, mutect2, varscan2
- BCAS3 | c.1674dup p.A559Sfs*6 | Frame Shift Ins (INS) | VAF 18/55 reads (33%) | called by mutect2, pindel, varscan2
- CDON | c.2241G>C p.G747= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as COSV99701422; called by muse, mutect2, varscan2
- CEMIP2 | c.160C>A p.R54= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as rs764170402, COSV100987393, COSV65485793; called by muse, mutect2, varscan2
- CNOT3 | c.780G>A p.T260= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs751333148, COSV55365019, COSV99651889; called by muse, mutect2, varscan2
- COG7 | c.2115A>G p.P705= | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as COSV100207572; called by muse, mutect2, varscan2
- COL16A1 | c.2013A>G p.K671= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV99594544; called by muse, mutect2, varscan2
- DAGLA | c.2097C>G p.L699= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as COSV99944406; called by muse, mutect2, varscan2
- DHRS9 | c.600C>T p.H200= | Silent (SNP) | VAF 41/67 reads (61%) | catalogued as rs761781142, COSV59141072; called by muse, mutect2, varscan2
- DPP6 | c.1983C>T p.D661= (on ENST00000377770 / NM_001364500.2; = p.D599= on NM_001936.5) | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as rs372493523; called by muse, mutect2, varscan2
- FAM174A | c.267C>T p.A89= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs766666353, COSV100444446; called by muse, mutect2, varscan2
- LRRC30 | c.741C>A p.L247= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV101274414; called by muse, mutect2, varscan2
- NOBOX | c.1281C>T p.P427= | Silent (SNP) | VAF 58/99 reads (59%) | catalogued as COSV99779465; called by muse, mutect2, varscan2
- NUDT10 | c.117C>T p.S39= | Silent (SNP) | VAF 106/137 reads (77%) | catalogued as COSV100726821; called by muse, varscan2
- SDK2 | c.1065C>G p.T355= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs937364517, COSV101167692; called by muse, mutect2, varscan2
- SLIT3 | c.918G>A p.P306= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs147887398; called by muse, mutect2, varscan2
- SYNM | c.2074C>T p.L692= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV100152762; called by muse, mutect2, varscan2
- TULP4 | c.1849C>T p.L617= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100893519; called by muse, mutect2, varscan2
